Somatic mutation profile of tumor specimen TCGA-50-5068-01A (aliquot TCGA-50-5068-01A-01D-1625-08) from TCGA case TCGA-50-5068, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIB; Age at diagnosis: 59.5 years (21,728 days).
Specimen TCGA-50-5068-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d29ef000-c302-4c1f-9f2d-8d95c9fff74e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-50-5068-10A (Blood Derived Normal), aliquot TCGA-50-5068-10A-01D-1625-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5eb83ba5-23cf-4a7e-b674-00191ffd8a8e

The open-access MAF lists 96 somatic variants for this specimen: 73 protein-altering or splice-affecting, 22 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 64, Silent 22, Splice Site 3, Nonsense Mutation 2, In Frame Del 2, Frame Shift Del 2, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACCSL | c.1504C>T p.L502F | Missense Mutation (SNP) | VAF 20/137 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.82); catalogued as COSV66582563; called by muse, mutect2, varscan2
- AMER3 | c.896C>T p.A299V | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.863); catalogued as rs181225754, COSV58466967; called by muse, mutect2, varscan2
- ANKRD30A | c.1573C>A p.P525T (on ENST00000611781; = p.P469T on NM_052997.2) | Missense Mutation (SNP) | VAF 9/83 reads (11%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.981); catalogued as COSV64619137; called by muse, mutect2, varscan2
- ATP5F1C | c.592A>T p.T198S | Missense Mutation (SNP) | VAF 31/180 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.184); catalogued as COSV59622814; called by muse, mutect2, varscan2
- BCL9 | c.3677C>A p.P1226H | Missense Mutation (SNP) | VAF 15/112 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52349334; called by muse, mutect2
- CAPN9 | c.301G>A p.A101T | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55238780; called by muse, varscan2
- CCDC7 | c.2608G>T p.V870L | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.976); catalogued as COSV56550495; called by muse, mutect2, varscan2
- CD93 | c.1849_1851del p.K617del | In Frame Del (DEL) | VAF 24/152 reads (16%) | catalogued as rs755784829; called by pindel, varscan2
- CDH10 | c.1876G>T p.V626F | Missense Mutation (SNP) | VAF 18/84 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.047); catalogued as COSV52594566; called by muse, mutect2
- CECR2 | c.2674G>T p.G892W (on ENST00000342247 / NM_001290047.2; = p.G709W on NM_001290046.1) | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52847206; called by muse, mutect2, varscan2
- CFAP43 | c.4884G>A p.M1628I | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as COSV60479827; called by muse, mutect2, varscan2
- CKAP2L | c.1821A>T p.E607D | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.067); catalogued as COSV56697991; called by muse, mutect2, varscan2
- CNGA4 | c.1072G>T p.E358* | Nonsense Mutation (SNP) | VAF 11/86 reads (13%) | catalogued as COSV66006920; called by muse, mutect2, varscan2
- CSMD3 | c.367G>A p.D123N | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); catalogued as COSV52296419; called by muse, varscan2
- DOCK7 | c.5854C>T p.R1952C (on ENST00000635253 / NM_001367561.1; = p.R1921C on NM_033407.3) | Missense Mutation (SNP) | VAF 28/140 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1210870491, COSV52019164; called by muse, mutect2, varscan2
- ENPP7 | c.751A>T p.T251S | Missense Mutation (SNP) | VAF 38/99 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.03); catalogued as COSV60387688; called by muse, mutect2, varscan2
- EPHA4 | c.1992G>T p.R664S | Missense Mutation (SNP) | VAF 8/120 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56029797, COSV56042660; called by muse, mutect2
- EPHB2 | c.1552C>T p.R518C | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.849); catalogued as rs369387828; called by muse, mutect2, varscan2
- EXTL3 | c.499G>A p.G167S | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT tolerated (0.74); PolyPhen benign (0.023); catalogued as rs1207644267, COSV55039045; called by muse, mutect2, varscan2
- FER1L6 | c.1469T>C p.M490T | Missense Mutation (SNP) | VAF 13/86 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as COSV67552453; called by muse, mutect2, varscan2
- FOLR1 | c.494-2A>C p.X165_splice | Splice Site (SNP) | VAF 19/103 reads (18%) | catalogued as COSV100398602; called by muse, mutect2, varscan2
- FRMPD4 | c.3296G>T p.G1099V | Missense Mutation (SNP) | VAF 18/107 reads (17%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.111); catalogued as COSV66221947; called by muse, mutect2, varscan2
- GUCY1A1 | c.620C>T p.P207L | Missense Mutation (SNP) | VAF 6/75 reads (8%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.914); catalogued as COSV56655729; called by muse, mutect2
- HCN1 | c.1042G>A p.A348T | Missense Mutation (SNP) | VAF 13/91 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as rs1333872397, COSV100298381, COSV57492101, COSV57537055; called by muse, mutect2, varscan2
- HNRNPCL1 | c.670C>G p.Q224E | Missense Mutation (SNP) | VAF 19/219 reads (9%) | SIFT tolerated (0.31); PolyPhen benign (0.034); catalogued as COSV58614710; called by muse, mutect2
- IL18RAP | c.922A>G p.I308V | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT tolerated (0.73); PolyPhen benign (0.003); catalogued as rs758711609, COSV51827085; called by muse, mutect2, varscan2
- ITGA8 | c.764C>A p.T255K | Missense Mutation (SNP) | VAF 29/148 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs587777281, CM140878, COSV65234883; called by muse, mutect2, varscan2
- KCNA1 | c.544G>A p.V182I | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as COSV101230141, COSV66838528; called by muse, mutect2, varscan2
- KRT80 | c.806A>C p.E269A | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100502958; called by muse, mutect2, varscan2
- LRIT1 | c.833C>T p.T278I | Missense Mutation (SNP) | VAF 13/90 reads (14%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.665); catalogued as COSV64513470; called by muse, mutect2, varscan2
- ME3 | c.421G>A p.V141M | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs150824447; called by muse, mutect2, varscan2
- MGAM | c.2422G>A p.G808R | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated (0.39); PolyPhen benign (0.135); catalogued as rs1335413349, COSV72075566; called by muse, mutect2, varscan2
- MYH2 | c.4919G>T p.R1640L | Missense Mutation (SNP) | VAF 19/96 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.334); catalogued as rs772914345, COSV55434719, COSV55447076; called by muse, mutect2, varscan2
- MYRF | c.2557C>A p.P853T (on ENST00000278836 / NM_001127392.3; = p.P818T on NM_013279.4) | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.335); catalogued as COSV53893361; called by muse, mutect2, varscan2
- NAV3 | c.3049G>A p.D1017N | Missense Mutation (SNP) | VAF 30/128 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs770984812, COSV57090774, COSV99887188; called by muse, mutect2, varscan2
- NETO1 | c.498G>C p.L166F | Missense Mutation (SNP) | VAF 17/105 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.319); catalogued as COSV55009403, COSV55014226; called by muse, mutect2, varscan2
- NLRP3 | c.1456G>A p.D486N | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); catalogued as COSV60227288, COSV60230215; called by muse, mutect2, varscan2
- OR1L8 | c.652T>C p.S218P | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59187209; called by muse, mutect2, varscan2
- OR52N2 | c.715G>A p.A239T | Missense Mutation (SNP) | VAF 10/140 reads (7%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.764); catalogued as COSV57677713; called by muse, mutect2
- OR9A2 | c.865C>T p.R289W | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.977); catalogued as rs374520156; called by muse, mutect2, varscan2
- P4HA1 | c.835G>T p.A279S | Missense Mutation (SNP) | VAF 40/255 reads (16%) | SIFT tolerated (0.88); PolyPhen benign (0.01); catalogued as COSV54964867; called by muse, mutect2, varscan2
- PPP1R15B | c.1460A>G p.Y487C | Missense Mutation (SNP) | VAF 22/110 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1304469614, COSV65816494; called by muse, mutect2, varscan2
- PRDM11 | c.1184G>T p.G395V (on ENST00000530656 / NM_001359633.1; = p.G361V on NM_001256695.1) | Missense Mutation (SNP) | VAF 26/145 reads (18%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.491); catalogued as COSV55443187; called by muse, mutect2, varscan2
- PTBP1 | c.115+1G>T p.X39_splice | Splice Site (SNP) | VAF 7/100 reads (7%) | catalogued as COSV100609182; called by muse, mutect2
- RBM34 | c.1134G>T p.K378N | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.131); catalogued as COSV100784090; called by muse, mutect2, varscan2
- RBM5 | c.1119+1G>A p.X373_splice | Splice Site (SNP) | VAF 10/69 reads (14%) | catalogued as COSV61738830; called by muse, mutect2, varscan2
- RBM5 | c.2276G>T p.G759V | Missense Mutation (SNP) | VAF 6/109 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61736467; called by muse, mutect2
- RXRG | c.365G>A p.G122E | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT tolerated (0.34); PolyPhen probably damaging (1); catalogued as COSV63233025; called by muse, mutect2, varscan2
- RYR1 | c.308G>A p.G103D | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62108657; called by muse, mutect2
- SAXO2 | c.655C>A p.R219S | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as COSV59755149; called by muse, mutect2, varscan2
- SBNO1 | c.2907G>C p.W969C (on ENST00000420886; = p.W968C on NM_018183.5) | Missense Mutation (SNP) | VAF 16/81 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57344253, COSV57345222; called by muse, mutect2, varscan2
- SEMA4C | c.1210G>T p.V404L | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.897); catalogued as COSV100561207; called by muse, mutect2, varscan2
- SERPINA5 | c.860T>A p.L287Q | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61574911, COSV61575168; called by muse, mutect2, varscan2
- SLC5A2 | c.1241G>A p.R414Q | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs766094285, COSV57889954; called by mutect2, varscan2
- SPPL2A | c.364C>G p.P122A | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.023); catalogued as COSV55941481, COSV55943050; called by muse, mutect2
- ST6GALNAC5 | c.403G>A p.V135M | Missense Mutation (SNP) | VAF 14/83 reads (17%) | PolyPhen probably damaging (0.999); catalogued as rs759920866, COSV100603118; called by muse, mutect2, varscan2
- SULF2 | c.1174A>C p.T392P | Missense Mutation (SNP) | VAF 28/183 reads (15%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.835); catalogued as COSV63419550; called by muse, mutect2, varscan2
- TBX19 | c.214C>T p.P72S | Missense Mutation (SNP) | VAF 35/206 reads (17%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as COSV63198303; called by muse, mutect2, varscan2
- THSD7B | c.4331A>G p.N1444S (on ENST00000272643; = p.N1442S on NM_001316349.2) | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT tolerated (0.22); PolyPhen benign (0.412); catalogued as rs1192284371, COSV55730613; called by muse, mutect2, varscan2
- TIMM8A | c.199G>A p.V67I | Missense Mutation (SNP) | VAF 33/169 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.192); catalogued as rs1054895, COSV58123472; called by muse, mutect2, varscan2
- TLR4 | c.2095G>C p.G699R (on ENST00000355622 / NM_138554.5; = p.G659R on NM_003266.4) | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100842853, COSV62924128; called by muse, mutect2, varscan2
- USP25 | c.2101G>C p.E701Q | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0.005); catalogued as rs1412596890, COSV53489564; called by muse, mutect2, varscan2
- USP26 | c.608A>G p.Y203C | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT tolerated (0.18); PolyPhen benign (0.214); catalogued as COSV100896780; called by muse, mutect2, varscan2
- VCAN | c.6028G>T p.G2010C | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1177283203, COSV99427534; called by muse, mutect2, varscan2
- VCAN | c.6935G>T p.G2312V | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.462); catalogued as rs1191876316, COSV54115000; called by muse, mutect2, varscan2
- XIRP2 | c.6297C>G p.I2099M (on ENST00000628543; = p.I2274M on NM_152381.6) | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.288); catalogued as rs779401246, COSV54684597, COSV54729716; called by muse, mutect2, varscan2
- ZIM2 | c.1511G>T p.G504V | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.085); catalogued as COSV55645140; called by muse, mutect2, varscan2
- ZNF709 | c.1292G>T p.C431F | Missense Mutation (SNP) | VAF 17/176 reads (10%) | SIFT tolerated (0.7); PolyPhen benign (0.003); catalogued as COSV67195743; called by muse, varscan2
- ZNF831 | c.3832C>T p.R1278C | Missense Mutation (SNP) | VAF 16/131 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.441); catalogued as rs776539508, COSV64040540; called by muse, mutect2, varscan2
- FAM47C | c.1741del p.H581Ifs*244 | Frame Shift Del (DEL) | VAF 11/66 reads (17%) | called by mutect2, varscan2
- IGHG1 | c.718G>T p.E240* | Nonsense Mutation (SNP) | VAF 8/74 reads (11%) | called by muse, mutect2, varscan2
- NELL2 | c.1830_1835del p.R610_H611del | In Frame Del (DEL) | VAF 12/72 reads (17%) | called by mutect2, pindel, varscan2
- NF1 | c.5852del p.P1951Hfs*6 (on ENST00000358273 / NM_001042492.3; = p.P1930Hfs*6 on NM_000267.3) | Frame Shift Del (DEL) | VAF 9/57 reads (16%) | called by mutect2, pindel, varscan2
- ABCB7 | c.1617G>T p.V539= (on ENST00000373394 / NM_001271696.3; = p.V540= on NM_004299.6) | Silent (SNP) | VAF 28/152 reads (18%) | catalogued as COSV53723053; called by muse, mutect2, varscan2
- CALHM1 | c.411A>C p.A137= | Silent (SNP) | VAF 10/35 reads (29%) | catalogued as COSV61708274; called by muse, mutect2, varscan2
- CASP9 | c.447A>T p.A149= | Silent (SNP) | VAF 10/87 reads (11%) | catalogued as COSV61602404; called by muse, mutect2
- CNTN4 | c.600G>T p.V200= | Silent (SNP) | VAF 8/71 reads (11%) | catalogued as COSV61879896; called by muse, mutect2, varscan2
- COL19A1 | c.2583A>C p.A861= | Silent (SNP) | VAF 11/42 reads (26%) | catalogued as COSV59585313; called by muse, mutect2, varscan2
- CSMD3 | c.303T>C p.N101= | Silent (SNP) | VAF 16/126 reads (13%) | catalogued as COSV52094793, COSV52296447; called by muse, varscan2
- DEFB123 | c.87T>C p.Y29= | Silent (SNP) | VAF 17/121 reads (14%) | catalogued as rs377702716, COSV66233123; called by muse, mutect2, varscan2
- DSG2 | c.2940T>C p.A980= | Silent (SNP) | VAF 18/56 reads (32%) | catalogued as COSV55202289; called by muse, mutect2, varscan2
- EEF1AKNMT | c.636C>T p.F212= (on ENST00000361735 / NM_015935.5; = p.F126= on NM_014955.3) | Silent (SNP) | VAF 22/110 reads (20%) | catalogued as rs1366946671, COSV62283742; called by muse, mutect2, varscan2
- EIF3I | c.648C>T p.D216= | Silent (SNP) | VAF 17/398 reads (4%) | catalogued as COSV61890266; called by muse, mutect2
- FFAR3 | c.117C>T p.F39= | Silent (SNP) | VAF 12/133 reads (9%) | catalogued as rs148149328, COSV100588087; called by muse, mutect2
- KCNC2 | c.1113T>G p.L371= | Silent (SNP) | VAF 10/50 reads (20%) | catalogued as COSV54378102; called by muse, mutect2, varscan2
- KCNK2 | c.231C>A p.A77= (on ENST00000444842 / NM_001017425.3; = p.A62= on NM_014217.4) | Silent (SNP) | VAF 12/83 reads (14%) | catalogued as COSV67209610; called by muse, mutect2, varscan2
- LTBP1 | c.720C>A p.S240= | Silent (SNP) | VAF 16/179 reads (9%) | catalogued as COSV63196538; called by muse, mutect2
- LUM | c.510G>A p.R170= | Silent (SNP) | VAF 6/86 reads (7%) | catalogued as COSV57128949; called by muse, mutect2
- OVCH1 | c.1725C>A p.I575= | Silent (SNP) | VAF 6/14 reads (43%) | catalogued as rs559859426, COSV58965958, COSV58966379; called by muse, mutect2, varscan2
- PIK3CG | c.501C>T p.N167= | Silent (SNP) | VAF 5/38 reads (13%) | catalogued as rs756855217, COSV63248867; called by muse, mutect2, varscan2
- PRPF6 | c.2778C>T p.I926= | Silent (SNP) | VAF 5/61 reads (8%) | catalogued as rs1412944012, COSV53877567; called by muse, mutect2
- RC3H1 | c.1956C>T p.N652= | Silent (SNP) | VAF 5/91 reads (5%) | catalogued as COSV51213749; called by muse, mutect2
- SLC2A7 | c.1218C>A p.T406= | Silent (SNP) | VAF 5/24 reads (21%) | catalogued as COSV68902313; called by muse, mutect2, varscan2
- SYNE1 | c.17763C>G p.S5921= (on ENST00000367255 / NM_182961.4; = p.S5850= on NM_033071.3) | Silent (SNP) | VAF 15/59 reads (25%) | catalogued as COSV55081444; called by muse, mutect2, varscan2
- ZNF813 | c.531C>T p.S177= | Silent (SNP) | VAF 27/154 reads (18%) | catalogued as COSV67177864; called by muse, mutect2, varscan2
- TTN | c.10360+3831dup | Intron (INS) | VAF 30/120 reads (25%) | called by mutect2, pindel, varscan2
